Somatic mutation profile of tumor specimen TCGA-DX-A6Z2-01A (aliquot TCGA-DX-A6Z2-01A-12D-A36J-09) from TCGA case TCGA-DX-A6Z2, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-DX-A6Z2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a617b3a7-f8e2-4007-baf6-01741f5eab0c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DX-A6Z2-11A (Solid Tissue Normal), aliquot TCGA-DX-A6Z2-11A-11D-A36M-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7e9f97f6-47ea-4796-8230-497da2e18d7f

The open-access MAF lists 63 somatic variants for this specimen: 52 protein-altering or splice-affecting, 10 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, Silent 10, Frame Shift Del 4, Nonsense Mutation 4, Splice Site 1, Frame Shift Ins 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB11 | c.1687C>T p.Q563* | Nonsense Mutation (SNP) | VAF 14/75 reads (19%) | catalogued as COSV55599261; called by muse, mutect2, varscan2
- ACTN3 | c.509G>A p.R170K | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.579); catalogued as COSV101557843; called by muse, mutect2, varscan2
- ALPL | c.613G>A p.A205T | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.474); catalogued as rs751455369, COSV66379873; called by muse, mutect2, varscan2
- ANO6 | c.527A>G p.K176R | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.4); PolyPhen benign (0.019); catalogued as COSV100263313; called by muse, mutect2, varscan2
- ARSG | c.383C>T p.A128V | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.768); catalogued as rs201030584, COSV101477900; called by muse, mutect2, varscan2
- AUTS2 | c.691-1G>C p.X231_splice | Splice Site (SNP) | VAF 8/84 reads (10%) | catalogued as COSV100717561; called by muse, mutect2
- CASD1 | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 57/149 reads (38%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.992); catalogued as COSV99802658; called by muse, mutect2, varscan2
- CLIC4 | c.650T>C p.I217T | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.153); catalogued as COSV100978160; called by muse, mutect2, varscan2
- CNOT1 | c.2283T>G p.N761K | Missense Mutation (SNP) | VAF 36/111 reads (32%) | SIFT tolerated (0.96); PolyPhen probably damaging (0.932); catalogued as COSV100409431; called by muse, mutect2, varscan2
- CUL4B | c.656A>C p.K219T | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.942); catalogued as COSV100340642; called by muse, mutect2, varscan2
- DIAPH2 | c.1067C>G p.S356* | Nonsense Mutation (SNP) | VAF 46/141 reads (33%) | catalogued as rs1338878948, COSV100233193; called by muse, mutect2, varscan2
- FAM214B | c.247C>A p.P83T | Missense Mutation (SNP) | VAF 58/180 reads (32%) | SIFT tolerated, low confidence (0.17); PolyPhen probably damaging (0.996); catalogued as COSV100521348; called by muse, mutect2, varscan2
- FGD1 | c.2302C>T p.R768W | Missense Mutation (SNP) | VAF 14/215 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.487); catalogued as COSV64308957; called by muse, mutect2
- FMR1 | c.967G>A p.E323K | Missense Mutation (SNP) | VAF 57/179 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.411); catalogued as COSV99503349; called by muse, mutect2, varscan2
- FUNDC1 | c.238G>C p.G80R | Missense Mutation (SNP) | VAF 48/153 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV100953643, COSV65181642; called by muse, mutect2, varscan2
- KCTD3 | c.205G>T p.A69S | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV99379343; called by muse, mutect2, varscan2
- KNL1 | c.4249C>G p.L1417V (on ENST00000346991 / NM_170589.5; = p.L1391V on NM_144508.5) | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.045); catalogued as COSV100706567; called by muse, mutect2, varscan2
- MAP9 | c.1689G>A p.W563* | Nonsense Mutation (SNP) | VAF 17/47 reads (36%) | catalogued as rs958058502, COSV100250918; called by muse, mutect2, varscan2
- MED12L | c.1010C>T p.P337L | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.098); catalogued as COSV99853440; called by muse, mutect2
- NRXN1 | c.887T>G p.L296W | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as COSV100455425; called by muse, mutect2, varscan2
- NUP155 | c.916G>A p.G306R (on ENST00000231498 / NM_153485.3; = p.G247R on NM_004298.4) | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1561804933, COSV99193025; called by muse, mutect2, varscan2
- OR5AP2 | c.781A>T p.I261F | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as COSV100266253; called by muse, mutect2, varscan2
- OR7C1 | c.223T>A p.S75T | Missense Mutation (SNP) | VAF 39/105 reads (37%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.176); catalogued as COSV99934891; called by muse, mutect2, varscan2
- PCDHA6 | c.1177G>A p.V393I | Missense Mutation (SNP) | VAF 42/106 reads (40%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.042); catalogued as rs1194699670, COSV101134309; called by muse, mutect2, varscan2
- PCLO | c.11341C>T p.R3781* | Nonsense Mutation (SNP) | VAF 18/46 reads (39%) | catalogued as rs865939646, COSV61646028; called by muse, mutect2, varscan2
- PKP4 | c.3220A>T p.S1074C | Missense Mutation (SNP) | VAF 56/143 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.315); catalogued as COSV100733863; called by muse, mutect2, varscan2
- PPFIA1 | c.1515A>T p.E505D | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT tolerated (0.28); PolyPhen benign (0.021); catalogued as rs776510315, COSV99557511; called by muse, mutect2, varscan2
- PTCHD4 | c.2083A>G p.I695V | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (1); PolyPhen benign (0.06); catalogued as rs1199286095, COSV59786466; called by muse, mutect2, varscan2
- PTPRG | c.2642T>G p.I881S | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.326); catalogued as COSV99875259; called by muse, mutect2, varscan2
- RASGRF1 | c.1103A>T p.D368V | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT tolerated (0.21); PolyPhen benign (0.275); catalogued as COSV101369654; called by muse, mutect2, varscan2
- RB1 | c.1001G>T p.R334I | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.937); catalogued as COSV57306978, COSV99925043; called by muse, mutect2, varscan2
- RTF1 | c.1619A>T p.N540I | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV101047869; called by muse, mutect2, varscan2
- RUNX1T1 | c.1144C>G p.Q382E (on ENST00000265814 / NM_001198628.1; = p.Q355E on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV99752501; called by muse, mutect2, varscan2
- RUVBL2 | c.617G>C p.G206A | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99669039; called by muse, mutect2, varscan2
- SCNN1B | c.1304C>T p.A435V | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as rs1027578512, COSV56301524; called by muse, mutect2, varscan2
- SGMS1 | c.1159C>G p.R387G | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.766); catalogued as COSV100693422, COSV62369102; called by muse, mutect2, varscan2
- SGTB | c.498G>T p.L166F | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.483); catalogued as COSV101121602; called by muse, mutect2, varscan2
- SOX21 | c.325C>A p.P109T | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0.078); catalogued as COSV100977924; called by muse, mutect2
- SPRY3 | c.358G>A p.G120R | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.991); catalogued as COSV100249371; called by muse, mutect2, varscan2
- TGM7 | c.325G>A p.A109T | Missense Mutation (SNP) | VAF 47/117 reads (40%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.724); catalogued as rs777130001, COSV101476867; called by muse, mutect2, varscan2
- THADA | c.4784C>T p.A1595V | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as COSV100368754; called by muse, mutect2, varscan2
- TMED4 | c.74C>T p.T25I | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs773564253, COSV99215557; called by muse, mutect2, varscan2
- TP53 | c.1051A>G p.K351E | Missense Mutation (SNP) | VAF 17/27 reads (63%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.515); catalogued as rs141402957, COSV52745104, COSV52944131; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ULK4 | c.2935G>T p.D979Y | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.188); catalogued as COSV100093064; called by muse, mutect2, varscan2
- ZCCHC8 | c.899G>C p.G300A | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1483754954, COSV100288689; called by muse, mutect2, varscan2
- ZFYVE9 | c.1550C>T p.S517L | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.057); catalogued as COSV99820112; called by muse, mutect2, varscan2
- CEP350 | c.6984_6993del p.M2328Ifs*8 | Frame Shift Del (DEL) | VAF 23/77 reads (30%) | called by mutect2, pindel, varscan2
- IGHG3 | c.370C>G p.P124A | Missense Mutation (SNP) | VAF 40/76 reads (53%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, mutect2, varscan2
- MLLT6 | c.3079del p.L1027* | Frame Shift Del (DEL) | VAF 8/20 reads (40%) | called by mutect2, varscan2
- MTR | c.2650del p.L884Wfs*14 | Frame Shift Del (DEL) | VAF 20/65 reads (31%) | called by mutect2, pindel, varscan2
- PTPRZ1 | c.790dup p.C264Lfs*2 | Frame Shift Ins (INS) | VAF 10/64 reads (16%) | called by mutect2, pindel, varscan2
- SYNPO2 | c.1869_1905del p.A624Ffs*32 | Frame Shift Del (DEL) | VAF 6/50 reads (12%) | called by mutect2, pindel
- ITPRID2 | c.3324A>G p.Q1108= | Silent (SNP) | VAF 24/84 reads (29%) | catalogued as COSV100238370; called by muse, mutect2, varscan2
- LAMA2 | c.2925G>A p.K975= | Silent (SNP) | VAF 18/71 reads (25%) | catalogued as COSV101370517; called by muse, mutect2, varscan2
- OR8B2 | c.303G>C p.L101= | Silent (SNP) | VAF 4/51 reads (8%) | catalogued as COSV100899413; called by muse, mutect2
- PIGF | c.27A>G p.L9= | Silent (SNP) | VAF 34/83 reads (41%) | catalogued as COSV99482750; called by muse, mutect2, varscan2
- PLA2G5 | c.279C>T p.G93= | Silent (SNP) | VAF 19/67 reads (28%) | catalogued as rs1387582322, COSV100908204, COSV64282754; called by muse, mutect2, varscan2
- RNASE12 | c.18A>T p.I6= | Silent (SNP) | VAF 11/35 reads (31%) | catalogued as COSV100250545; called by muse, mutect2, varscan2
- SLC26A7 | c.864T>C p.G288= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as COSV99403519; called by muse, mutect2, varscan2
- TMPRSS11E | c.915T>C p.F305= | Silent (SNP) | VAF 32/112 reads (29%) | catalogued as COSV100542398; called by muse, mutect2, varscan2
- TRAF3 | c.1083G>A p.V361= | Silent (SNP) | VAF 17/25 reads (68%) | catalogued as COSV61025266; called by muse, mutect2, varscan2
- UBC | c.1824G>A p.G608= | Silent (SNP) | VAF 35/72 reads (49%) | catalogued as COSV100299007; called by muse, mutect2, varscan2
- MUC2 | chr11:1099160 A>G | 3'Flank (SNP) | VAF 17/116 reads (15%) | catalogued as rs57664273; called by muse, varscan2
